Gene-level copy-number profile of tumor specimen TCGA-D8-A1Y3-01A from TCGA case TCGA-D8-A1Y3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.1 years (22,317 days).
Specimen TCGA-D8-A1Y3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0da7828c-fa60-464e-bf84-43de16003663.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1Y3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4673573d-e79f-4e86-b2b5-dafd0def2d85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,089; copy number 2: 23,674; copy number 3: 19,812; copy number 4: 10,466; copy number 5: 167; copy number 7: 13; copy number 10: 60; copy number 11: 248; copy number 12: 131; copy number 13: 92; copy number 14: 116; copy number 15: 494; copy number 17: 296; copy number 18: 116; copy number 20: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1Y3-01A-11D-A160-01): tumor purity 0.71, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:108,441,880–108,684,774, 4 genes: AL139106.1, AL391646.1, FOXO3, SUMO2P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,775 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,026,318–40,097,260, 36 genes, copy number 5: NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1.
- chr1:169,132,531–169,367,948, 2 genes, copy number 5 (within-gene range 4–5): NME7, Z99758.1.
- chr3:1,008,135–2,089,211, 9 genes, copy number 5: AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 5: CNTN4-AS2, AC087427.1.
- chr7:145,583,197–148,420,998, 15 genes, copy number 5 (within-gene range 4–5): DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P.
- chr7:153,355,365–153,748,986, 4 genes, copy number 5: LINC01287, AC073236.1, PAXBP1P1, AC005998.1.
- chr7:153,968,665–154,096,043, 4 genes, copy number 5: AC005588.1, AC006019.3, AC006019.1, AC006019.2.
- chr8:37,559,992–39,284,917, 61 genes, copy number 10–18 (within-gene range 3–18) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 10–20 (broad region; genes not listed).
- chr9:135,343,249–135,591,975, 13 genes, copy number 7: C9orf62, AL353615.1, SOCS5P2, PPP1R26-AS1, PPP1R26, C9orf116, MRPS2, AL161452.1, LCN1, OBP2A, PAEP, LINC01502, PAEPP1.
- chr11:23,730,588–25,631,041, 11 genes, copy number 5: LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1.
- chr11:37,702,125–40,112,599, 14 genes, copy number 5: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr11:40,351,564–40,513,269, 2 genes, copy number 5: Y_RNA, AC090720.1.
- chr11:79,604,967–81,556,425, 12 genes, copy number 5: AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 5: AP002802.2, MIR4300, AP002802.1.
- chr11:97,657,464–101,129,813, 16 genes, copy number 5 (within-gene range 4–5): RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR.
- chr12:114,504,876–115,364,745, 18 genes, copy number 5: RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2.
- chr13:38,567,715–39,857,227, 19 genes, copy number 5: LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6, COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116.

Autosomal genes at a single copy (total copy number 1): 2,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
